Gene-level copy-number profile of tumor specimen TCGA-CN-6019-01A from TCGA case TCGA-CN-6019, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 61.6 years (22,485 days).
Specimen TCGA-CN-6019-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.dbc6f8f7-a059-448f-ac9d-9787ce0da3a2.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,157 have no estimate.
https://portal.gdc.cancer.gov/files/87e6f0cb-e1e7-4a51-b1da-ee96f20d46f8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 14,791; copy number 2: 38,800; copy number 3: 11; copy number 4: 1,836; copy number 6: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-6019-01A-11D-1682-01): tumor purity 0.36, ploidy 1.74, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:54,122,547–55,074,557, 5 genes (within-gene range 0–1): CACNA2D3, RPS15P5, ESRG, CACNA2D3-AS1, LRTM1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 23 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:15,928,296–16,645,467, 1 gene, copy number 6 (within-gene range 2–6): MIR99AHG.
- chr21:16,284,696–17,593,579, 22 genes, copy number 6: SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1, NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 14,791. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
